Somatic mutation profile of tumor specimen C3L-06089-54 (aliquot CPT0356520002) from CPTAC case C3L-06089, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.1 years (23,404 days).
Specimen C3L-06089-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1d3ef3-dfb1-404b-8b70-ed3c539b679b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06089-50 (Buccal Cell Normal), aliquot CPT0356590003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6c3f47-bb2a-49a1-a77b-83b1ea536613

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 2, 5'Flank 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1669T>C p.W557R | Missense Mutation (SNP) | VAF 155/385 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913235, CM005329, COSV55386440, COSV55387014, COSV55389479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749890033, COSV56066390; called by muse, mutect2, varscan2
- GATA2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 212/511 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003029, COSV62003510, COSV62004917; called by muse, mutect2, varscan2
- INTS1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199765283; called by muse, mutect2, varscan2
- MUC16 | c.6352G>A p.A2118T | Missense Mutation (SNP) | VAF 129/245 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749152513, COSV67455691; called by muse, mutect2, varscan2
- TET2 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455459760, COSV54397848, COSV54404337, COSV54432758; called by muse, mutect2, varscan2
- ASPM | c.8477G>C p.C2826S | Missense Mutation (SNP) | VAF 205/462 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CEBPA | c.129del p.A44Pfs*116 | Frame Shift Del (DEL) | VAF 52/155 reads (34%) | called by mutect2, pindel, varscan2
- CTRB1 | c.225_231del p.H75Qfs*25 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- EP300 | c.2029delinsGA p.Q677Efs*9 | Frame Shift Ins (INS) | VAF 52/240 reads (22%) | called by pindel, varscan2*
- PLAA | c.1641C>A p.N547K | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNOT1 | c.3585G>A p.L1195= | Silent (SNP) | VAF 62/139 reads (45%) | called by muse, mutect2, varscan2
- GTPBP3 | c.486G>A p.A162= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs781243432, COSV99344297; called by muse, mutect2, varscan2
- SDR9C7 | c.225C>T p.T75= | Silent (SNP) | VAF 125/263 reads (48%) | called by muse, mutect2, varscan2
- GNL3 | chr3:52686014 A>G | 5'Flank (SNP) | VAF 101/228 reads (44%) | catalogued as rs530947159, COSV66921042; called by muse, mutect2, varscan2
- TRPM1 | c.213+52G>A | Intron (SNP) | VAF 147/282 reads (52%) | catalogued as rs760249631; called by muse, mutect2, varscan2
